Surgical pathology report (de-identified scan), TCGA case TCGA-JU-AAVI, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site BLN - Baylor, specimen TCGA-JU-AAVI-01A (Primary Tumor).

[page 1 of 5]
Results

SURGICAL PATHOLOGY

Entry Date

Component Results

Component

Surgical Pathology

(note)

Name

Date of Birth

Hospital Number

Location

SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

ESCP *ICD-O3*
Adenocarcinoma, serous NOS 8441/3
path Carcinoma, serous NOS 8441/3
Site: Endometrium C54.1
2/19/14

PATHOLOGIC DIAGNOSIS

A. UTERUS, CERVIX, BILATERAL FALLOPIAN TUBES AND OVARIES, HYSTERECTOMY WITH BILATERAL

SALPINGO-OOPHERECTOMY:

- UTERINE CORPUS:

- SEROUS CARCINOMA OF THE ENDOMETRIUM
- TUMOR SIZE: CANNOT BE DETERMINED
(DIFFUSELY INVOLVES ANTERIOR AND POSTERIOR ENDOMYOMETRIUM)
- DEPTH OF MYOMETRIAL INVASION: 25 mm of 27 mm
- EXTENSIVE LYMPH-VASCULAR SPACE INVASION PRESENT
- TUMOR EXTENDS TO THE LOWER UTERINE SEGMENT
- LEIOMYOMATA
- UNREMARKABLE UTERINE SEROSA

- UTERINE CERVIX:

- NO DYSPLASIA OR TUMOR PRESENT
(ENTIRE CERVIX SUBMITTED FOR HISTOPATHOLOGIC EXAM)
- ATROPHY

- BILATERAL FALLOPIAN TUBES:

- NO TUMOR PRESENT

- BILATERAL OVARIES:

- NO TUMOR PRESENT

B. LYMPH NODE, RIGHT PELVIC, EXCISION:

- METASTATIC CARCINOMA INVOLVING TWO OF TEN LYMPH NODES (2/10)

C. LYMPH NODE, RIGHT PERIAORTIC, EXCISION:

- NO TUMOR PRESENT IN ONE LYMPH NODE (0/1)

D. LYMPH NODE, LEFT PELVIC, EXCISION:

- NO TUMOR PRESENT IN FIVE LYMPH NODES (0/5)

E. SOFT TISSUE, PARACAVAL, RESECTION:

- FIBROADIPOSE TISSUE, NO TUMOR PRESENT

F. LYMPH NODE, LEFT PERIAORTIC, EXCISION:

- NO TUMOR PRESENT IN ONE LYMPH NODE (0/1)

G. LYMPH NODE, LEFT EXTERNAL ILIAC, EXCISION:

- NO TUMOR PRESENT IN ONE LYMPH NODE (0/1)

[page 2 of 5]
Pathologic Staging (pTNM [FIGO]): Stage IIIC1

Primary Tumor (pT1b): Tumor invades outer half of myometrium

Regional Lymph Nodes (pN1): Regional lymph node metastasis to pelvic lymph nodes (2/18)

Pelvic lymph nodes:

Number of Lymph Nodes Examined: 16

Number of Lymph Nodes Involved: 2

Para-aortic lymph nodes:

Number of Lymph Nodes Examined: 2

Number of Lymph Nodes Involved: 0

Distant Metastasis (pM): Not applicable

Staff Pathologist

Comment

Immunohistochemistry is performed and the tumor is diffusely positive with AE1/AE3. Immunohistochemical stains performed on the biopsy showed diffuse staining for p53 and p16, and no staining for ER, in keeping with the above diagnosis.

Pertinent Clinical Information

A -year-old with endometrial carcinoma/post menopausal bleeding.

Gross Description

Specimen Material: A. Uterus, cervix, bilateral tubes and ovaries. B. Right pelvic lymph node. C. Right periaortic lymph node. D. Left pelvic lymph node. E. Dense paracaval tissue. F. Left paraaortic lymph node. G. Left external iliac lymph node.

The case is received in seven parts labeled with the patient's name

, medical record number and given accession number

and it is accompanied by a requisition form labeled with the same name and accession number.

Part A. Received in formalin labeled "UTERUS, CERVIX, BILATERAL TUBES AND OVARIES," is a 242 gram uterus (10 x 9 x 7 cm), cervix (2.5 x 2.5 cm), right adnexa (4 x 2.5 x 0.4 cm), and left adnexa (4 x 2 x 0.4 cm).

The external surface of the uterus is tan-pink smooth and glistening. The uterus is bivalved to reveal a tan-pink endometrial cavity (6 x 4 x 1 cm) that is distorted by a calcified submucosal leiomyoma (6.0 x 6.0 x 4.0 cm). The endometrium displays a tan-yellow, exophytic tumor which is present on the anterior (3 x 2 x 2 cm) and posterior surface (4 x 3 x 2 cm) with no gross extension to the cervix. The tumor invades greater than 50% of the myometrial thickness and comes to within 0.3 cm of the serosa on the posterior aspect. The uninvolved myometrium is tan-pink and trabeculated with a thickness ranging from 1.8 to 2.0 cm. Within the myometrium of the posterior lower uterine segment, there is another calcified leiomyoma measuring 1.5 cm as well as additional intramural leiomyomas less than 1 cm. Tumor is submitted for tissue banking.

The right adnexa is comprised of an unremarkable ovary (2.5 x 1.5 x 0.4 cm) and fallopian tube (4 cm in length x 0.4 cm in diameter) with multiple small paratubal cysts.

The left adnexa is comprised of an unremarkable ovary (2 x 1.5 x 0.4 cm) and fallopian tube (4 cm in length x 0.4 cm in diameter) with a single 1cm paratubal cyst.

[page 3 of 5]
Ink code:

Blue: Anterior uterus

Black: Posterior uterus

Section code:

- A1 anterior cervix (12 o'clock)
- A2 anterior lower uterine segment
- A3 6 anterior endomyometrium, full thickness sections
- A7 8 additional anterior tumor
- A9 10 anterior endomyometrium with leiomyoma and tumor
- A11 13 cervix from 12 to 3 o'clock
- A14 15 cervix from 9 to 12 o'clock
- A16 posterior cervix (6 o'clock)
- A17 posterior lower uterine segment
- A18 19 posterior endomyometrium, full thickness sections
- A20 27 posterior tumor
- A28 representative sections of non-calcified portion of largest leiomyoma
- A29 31 cervix from 3 to 6 o'clock
- A32 34 cervix from 6 to 9 o'clock
- A35 right fallopian tube, representative sections
- A36 right ovary, representative sections
- A37- right fallopian tube, representative sections
- A38 left ovary, representative sections

Part B. Received in formalin labeled "RIGHT PELVIC LYMPH NODE," and consists of a 6 x 5.7 x 1.9 cm aggregate of tan-yellow fibrofatty tissue which is palpated to reveal five possible lymph nodes ranging from 1 to 2 cm in greatest dimension. The larger lymph nodes are bisected to reveal a tan-pink to tan-white and hemorrhagic variegated cut surface. The lymph nodes are submitted in their entirety as follows:

- B1 B4 one lymph node bisected in each
- B5 one whole lymph node

Part C. Received in formalin labeled "PERIAORTIC LYMPH NODES, RIGHT," and consists of a 4 x 2.6 x 1.7 cm aggregate of fibrofatty tissue which is palpated to reveal a 4.5 x 1 x 0.6 cm tan-pink possible lymph node which is serially sectioned to reveal a tan-white smooth cut surface. The lymph node is submitted in its entirety in cassette C1-C3.

Part D. Received in formalin labeled "PELVIC LYMPH NODE LEFT," and consists of a 5.7 x 5.5 x 1.7 cm aggregate of tan-yellow fibrofatty tissue which is palpated to reveal four possible lymph nodes that range from 0.9 to 4.2 cm in greatest dimension. The larger lymph nodes are serially sectioned to reveal a tan-pink to red smooth cut surface. Five possible lymph nodes are identified in the fibrofatty tissues. The lymph nodes are submitted in their entirety as follows:

- D1 one lymph node, trisected
- D2 one lymph node, bisected
- D3 4 one lymph node, serially sectioned
- D5 two possible whole lymph nodes

Part E. Received in formalin labeled "DENSE PARACAVAL TISSUE," and consists of a 0.6 x 0.5 x 0.3 cm tan-pink irregular soft tissue which is submitted in its entirety in cassette E.

Part F. Received in formalin labeled "LEFT PARAAORTIC LYMPH NODE," and consists of a 2.7 x 2.1 x 0.7 cm aggregate of tan-yellow fibrofatty tissue which is palpated to reveal one possible lymph node that measures 0.7 cm in greatest dimension. The specimen is submitted in its entirety as follows:

[page 4 of 5]
F1 lymph node in its entirety
F2 remaining fibrofatty tissue

Part G. Received in formalin labeled "LEFT EXTERNAL ILIAC LYMPH NODE," and consists of a 1.8 x 1 x 0.8 cm ovoid portion of tan-pink soft tissue consistent with lymphoid tissue. The specimen is bisected to reveal a tan-white to red, smooth cut surface. The specimen is submitted in its entirety in cassette G1.

Pathology Resident
Microscopic Description
Performed.

The staff pathologist listed below has reviewed this case.

Synoptic Report

Specimen: Uterus with cervix, bilateral fallopian tubes and ovaries
Procedure: Simple hysterectomy and bilateral salpingo-oophorectomy
Lymph Node Sampling: Bilateral pelvic, bilateral periaortic, left external iliac
Tumor Site: Anterior and posterior endometrium
Tumor Size: Cannot be determined (tumor diffusely involves anterior and posterior endomyometrium)
Histologic Type: Serous carcinoma
Myometrial invasion: Present
Depth of invasion: 25 mm
Myometrial thickness: 27 mm
Involvement of Cervix: Not involved
Extent of Involvement of Other Organs: Bilateral tubes and ovaries: Not involved
Lymph-Vascular Invasion: Present, extensive

Pathologic Staging (pTNM [FIGO]): Stage IIIC1
Primary Tumor (pT1b): Tumor invades outer half of myometrium
Regional Lymph Nodes (pN1): Regional lymph node metastasis to pelvic lymph nodes (2/18)
Pelvic lymph nodes:
Number of Lymph Nodes Examined: 16
Number of Lymph Nodes Involved: 2
Para-aortic lymph nodes:
Number of Lymph Nodes Examined: 2
Number of Lymph Nodes Involved: 0
Distant Metastasis (pM): Not applicable

****Electronically Signed Out****

Staff Pathologist

Result History

PATHOLOGY (Order on - Order Result History Report.

Lab Information

Resulting Lab

Order Information

Order Date Order Time

[page 5 of 5]
Result Information

Result Date and Time	Status Final result	Priority Routine
----------------------	------------------------	---------------------

Received Date/Time

Received Date	Received Time
---------------	---------------

Order Providers

Authorizing Provider	Encounter Provider None
----------------------	----------------------------

Encounter[View Encounter](#)**Order****SURGICAL PATHOLOGY****Administration Details**

No Administrations
Recorded

Order Information

Order Date/Time	Release Date/Time	Start Date/Time	End Date/Time
-----------------	-------------------	-----------------	---------------

Order Details

Frequency ONCE	Duration 1 occurrence	Priority Routine	Order Class Normal
-------------------	--------------------------	---------------------	-----------------------

Quantity

Ordering Quantity
1

Comments

Ordered by

Original Order

Ordered On	Ordered By
------------	------------

Collection Information

Collection Date	Collection Time	Resulting Agency
-----------------	-----------------	------------------

Provider Information

Ordering User	Ordering Provider	Authorizing Provider
Attending Provider(s)	Admitting Provider	PCP

Order-Level Documents:

There are no order-level documents.

Encounter[View Encounter](#)**Orders Needing Specimen Collection**

** None **

Source: NCI Genomic Data Commons file 0095de78-33b8-4a0e-b9f2-97aa21b904b3 (TCGA-JU-AAVI.8639CE54-3D67-4E2E-BECB-26755EE726C5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).